Surgical pathology report (de-identified scan), TCGA case TCGA-12-5295, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-5295-01A (Primary Tumor).

Patient: [REDACTED]

AP Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

TCGA-12-5295

Surg Path [REDACTED]

CLINICAL HISTORY:

[REDACTED] MRI [REDACTED]: There is a large, predominantly nonenhancing, T2 hyperintense mass identified within the right temporal lobe. The most superior component of this mass likely involves the inferior right parietal white matter. Although the borders of this mass are well defined lack of multiplanar imaging limits evaluation of size. The greatest transaxial dimensions are 53 x 37 mm on image 8 series 5. Within the larger T2 hyperintense mass they're all are peripherally enhancing foci, most prominently anteriorly within the right temporal lobe as demonstrated on image 50 series 4. Mass effect upon the mesial right temporal lobe and effacement of the right basilar cisterns are not significantly changed when compared to the prior study.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section is a 7 x 5 x 3 cm portion of focally hemorrhagic, friable brain tissue. Representative is frozen as AF1, frozen remnant submitted in A1. Additional sections are submitted in A2-4.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis. The tumor also exhibits evidence of a previous surgical resection site.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).
PREVIOUS SURGICAL RESECTION SITE EVIDENT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Attending MD: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 96710eda-1fc4-42f1-8ade-4bb35c1389a9 (TCGA-12-5295.AD20D555-7675-41C6-A22E-0C30DB820B0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).